Somatic mutation profile of tumor specimen TCGA-04-1648-01A (aliquot TCGA-04-1648-01A-01W-0639-09) from TCGA case TCGA-04-1648, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 57.8 years (21,113 days).
Specimen TCGA-04-1648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4e2a01b-82dd-4436-8b2b-2a2f8f286346.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1648-11A (Solid Tissue Normal), aliquot TCGA-04-1648-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1a09f5d-6146-4683-a3a5-a30ff020c1a6

The open-access MAF lists 73 somatic variants for this specimen: 49 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 22, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.1536C>G p.I512M | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100383671; called by muse, mutect2
- ATF7IP2 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100202880; called by muse, mutect2
- CABS1 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 169/410 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV56733150; called by muse, mutect2, varscan2
- CBLN2 | c.392C>G p.A131G | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); catalogued as COSV99504744; called by muse, mutect2
- CDK5RAP2 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100575824; called by muse, mutect2
- CNTN1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 122/295 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs201607834, COSV61637219; called by muse, mutect2, varscan2
- CSF1R | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV53830678; called by muse, mutect2, varscan2
- DEK | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV55236898; called by muse, mutect2
- ERAP2 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as COSV101163989; called by muse, mutect2
- FBXO38 | c.3083G>T p.C1028F (on ENST00000340253 / NM_205836.3; = p.C953F on NM_030793.5) | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV99694152; called by muse, mutect2
- GNE | c.1611C>A p.D537E (on ENST00000396594 / NM_001128227.3; = p.D506E on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/578 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.019); catalogued as COSV100930168; called by muse, mutect2
- GNLY | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99809065; called by muse, mutect2
- GOLGA7 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV100752873; called by muse, mutect2
- IFNW1 | c.156T>A p.C52* | Nonsense Mutation (SNP) | VAF 134/324 reads (41%) | catalogued as COSV66521861; called by muse, mutect2, varscan2
- IGHM | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs782579930; called by muse, mutect2
- MAGEB1 | c.437T>A p.F146Y | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV66775426; called by muse, mutect2, varscan2
- MCFD2 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV60177804; called by muse, mutect2, varscan2
- MRTFA | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV62932053; called by muse, mutect2, varscan2
- NGFR | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as COSV50801769; called by muse, mutect2, varscan2
- NOL4 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV52341798; called by muse, mutect2, varscan2
- NPAS2 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100177245; called by muse, mutect2
- NXF3 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 144/412 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV67702933; called by muse, mutect2, varscan2
- OR2T2 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 69/703 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768533956, COSV100737833, COSV61618893; called by muse, mutect2
- OR6M1 | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 48/736 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100484229, COSV58433764; called by muse, mutect2
- PDE4DIP | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 53/366 reads (14%) | catalogued as COSV100522530, COSV57694537; called by muse, mutect2, varscan2
- PIAS2 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100245593; called by muse, mutect2
- PTPRM | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161519; called by muse, mutect2
- RAPGEF2 | c.4363G>A p.G1455R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.021); catalogued as COSV52425781; called by muse, mutect2, varscan2
- RRM2B | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 21/486 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99310512; called by muse, mutect2
- RXFP2 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100034763; called by muse, mutect2
- SERPINE1 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 139/541 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs538785036, COSV56168998; called by muse, mutect2, varscan2
- SH3RF3 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV58681866; called by muse, mutect2
- SLC10A1 | c.812A>C p.N271T | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV53681993; called by muse, mutect2, varscan2
- SLC9A8 | c.1476del p.S492Rfs*44 | Frame Shift Del (DEL) | VAF 37/98 reads (38%) | catalogued as COSV64287595; called by mutect2, pindel, varscan2
- SMG6 | c.388C>A p.R130S | Missense Mutation (SNP) | VAF 75/635 reads (12%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.07); catalogued as rs138301573, COSV53964335; called by muse, mutect2, varscan2
- SPEN | c.2984C>A p.A995E | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV101005765; called by muse, mutect2
- SPOCK1 | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV99971362; called by muse, mutect2
- SPTB | c.3139C>A p.Q1047K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67630370; called by muse, mutect2
- STAG3 | c.1217C>A p.A406D | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100426252, COSV100426265; called by muse, mutect2
- TARBP1 | c.3868G>T p.A1290S | Missense Mutation (SNP) | VAF 11/368 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99242271; called by muse, mutect2
- TECTA | c.1107C>A p.H369Q | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99882059; called by muse, mutect2
- TTN | c.56752C>T p.Q18918* (on ENST00000591111; = p.Q11494* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/139 reads (6%) | catalogued as COSV100636098; called by muse, mutect2
- UAP1 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV99618192; called by muse, mutect2
- UBD | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100590216; called by muse, mutect2
- VOPP1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.203); catalogued as COSV53385456; called by muse, mutect2, varscan2
- VPS35L | c.2619G>T p.E873D | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99221984; called by muse, mutect2
- ZNF445 | c.3089G>A p.R1030K | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101253922; called by muse, mutect2, varscan2
- BAHD1 | c.2167del p.A723Pfs*76 | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- POGLUT2 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATP2C2 | c.2754C>T p.S918= | Silent (SNP) | VAF 43/270 reads (16%) | catalogued as rs375028020; called by muse, mutect2, varscan2
- ATRX | c.4249C>A p.R1417= | Silent (SNP) | VAF 28/536 reads (5%) | catalogued as COSV100971681; called by muse, mutect2
- EPS8L3 | c.1653T>G p.L551= (on ENST00000361965 / NM_133181.4; = p.L521= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV62608957; called by muse, mutect2, varscan2
- FAM135B | c.1128C>T p.S376= | Silent (SNP) | VAF 80/288 reads (28%) | catalogued as COSV52711894, COSV99419820; called by muse, mutect2, varscan2
- FGA | c.402G>T p.L134= | Silent (SNP) | VAF 19/196 reads (10%) | catalogued as COSV57393991; called by muse, mutect2, varscan2
- FLNB | c.4986C>A p.A1662= | Silent (SNP) | VAF 24/491 reads (5%) | catalogued as COSV99915634; called by muse, mutect2
- GRM8 | c.1959C>A p.V653= | Silent (SNP) | VAF 14/311 reads (5%) | catalogued as COSV58852605, COSV58870765; called by muse, mutect2
- IGSF6 | c.162C>T p.S54= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs760122055, COSV51678602; called by muse, mutect2, varscan2
- KIAA1217 | c.3036C>A p.G1012= | Silent (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- MAGEB3 | c.312G>T p.V104= | Silent (SNP) | VAF 41/295 reads (14%) | catalogued as COSV64396819; called by muse, mutect2
- METTL25 | c.1806G>A p.Q602= | Silent (SNP) | VAF 23/215 reads (11%) | catalogued as rs1216212558, COSV50258088; called by muse, mutect2, varscan2
- MRC1 | c.129C>T p.A43= | Silent (SNP) | VAF 249/375 reads (66%) | catalogued as rs781852223; called by muse, mutect2, varscan2
- NLRC5 | c.645C>A p.T215= | Silent (SNP) | VAF 63/1022 reads (6%) | catalogued as COSV99348553; called by muse, mutect2
- NOP9 | c.960G>A p.L320= | Silent (SNP) | VAF 107/1234 reads (9%) | catalogued as COSV99351266; called by muse, mutect2
- PLXNA4 | c.2892G>T p.G964= | Silent (SNP) | VAF 20/364 reads (5%) | catalogued as rs777684954, COSV100328104; called by muse, mutect2
- RHOC | c.396C>G p.A132= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV53516904; called by muse, mutect2, varscan2
- RNF19B | c.1557C>A p.L519= | Silent (SNP) | VAF 14/446 reads (3%) | catalogued as COSV99331881; called by muse, mutect2
- SLC35F5 | c.510C>T p.F170= | Silent (SNP) | VAF 41/442 reads (9%) | catalogued as COSV99830311; called by muse, mutect2
- SNX16 | c.18C>A p.V6= | Silent (SNP) | VAF 25/360 reads (7%) | catalogued as rs754368795, COSV100629735; called by muse, mutect2
- SNX17 | c.126G>T p.G42= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99278158; called by muse, mutect2
- TBX5 | c.1185C>T p.D395= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as COSV59859146; called by muse, varscan2
- USP53 | c.1335C>T p.S445= | Silent (SNP) | VAF 11/228 reads (5%) | catalogued as COSV99918155; called by muse, mutect2
- MTCL1 | c.2968-3128C>A | Intron (SNP) | VAF 86/195 reads (44%) | catalogued as COSV60404202; called by muse, mutect2, varscan2
- TDRD6 | c.*1C>A | 3'UTR (SNP) | VAF 32/570 reads (6%) | catalogued as COSV99221702; called by muse, mutect2
